FM case AD10381 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/bea67bf6-58fe-4369-b293-800af3a9bf4d

Male, 43.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues of thorax. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
